TARGET case TARGET-40-0A4I3S — Osteosarcoma (TARGET-OS)
Open-access clinical record from the NCI Genomic Data Commons (Data Release 46.0 - August 10, 2026). Disease type: Osseous and Chondromatous Neoplasms; Primary site: Bones, joints and articular cartilage of other and unspecified sites. Index date (day 0 for every day count below): diagnosis.
https://portal.gdc.cancer.gov/cases/1b925877-e79e-55b1-b9a7-6d3193e72db1

Demographics
Sex at birth: male; Race: black or african american; Age at index: 22 years; Vital status: Alive.

Diagnoses (1)
1. Osteosarcoma, NOS: ICD-O-3 morphology code: 9180/3; ICD-10 code: C41.4; Tissue or organ of origin: Pelvic bones, sacrum, coccyx and associated joints; Classification of tumor: primary; Age at diagnosis: 22.8 years (8,313 days); Year of diagnosis: 2007; Metastasis at diagnosis: No Metastasis; Days to last follow up: 1,844 days (5.0 years).
   Treatment given: Protocol identifier: IHRT.
   Treatment given: Therapeutic agents: Doxorubicin.
   Treatment given: Therapeutic agents: Platinum.

Follow-up (1 entry)
- Days to follow up: 1,844 days (5.0 years); Event-free: no event (relapse, second malignancy or death) recorded through day 1,844; Year of follow up: 2014.

Biospecimens (2 samples)
- Sample TARGET-40-0A4I3S-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue.
- Sample TARGET-40-0A4I3S-10A: Sample type: Blood Derived Normal; Tissue type: Normal; Specimen type: Peripheral Blood NOS.

Additional fields from the TARGET clinical supplement workbook TARGET_OS_ClinicalData_Discovery_20230709.xlsx (sheet Clinical Data):
- First Event: Censored
- Overall Survival Time in Days: 1844
- Disease at diagnosis: Non-metastatic (confirmed)
- Primary tumor site: Leg/foot
- Specific tumor site: Ilium
- Specific tumor region: Other, Posterior
- Definitive Surgery: Limb sparing
- Primary site progression: No
- Therapy: Adria/Plat
